Somatic mutation profile of tumor specimen TCGA-ED-A7PY-01A (aliquot TCGA-ED-A7PY-01A-11D-A33Q-10) from TCGA case TCGA-ED-A7PY, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 20.7 years (7,556 days).
Specimen TCGA-ED-A7PY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 997041ee-4e47-41ed-ab32-42e46fe05e31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ED-A7PY-10A (Blood Derived Normal), aliquot TCGA-ED-A7PY-10A-01D-A33Q-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14588732-daeb-4aec-bec1-fbe7503e66a3

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 7, Nonsense Mutation 4, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP2B1 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV52001715; called by muse, mutect2, varscan2
- ARHGAP33 | c.2929T>C p.Y977H | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV99140078; called by muse, mutect2, varscan2
- BIRC6 | c.2666T>C p.F889S | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV70203580; called by muse, mutect2, varscan2
- CDAN1 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as rs371090455; called by muse, mutect2, varscan2
- CLDN20 | c.504C>A p.F168L | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as rs1391123602, COSV65697255, COSV65697705; called by muse, mutect2, varscan2
- COL6A6 | c.3380A>G p.H1127R | Missense Mutation (SNP) | VAF 73/178 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV62032420; called by muse, mutect2, varscan2
- DYNC2H1 | c.4285T>A p.F1429I | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62101477; called by muse, mutect2, varscan2
- FMN2 | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 77/90 reads (86%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.655); catalogued as COSV60443764; called by muse, mutect2, varscan2
- HECW2 | c.1307G>A p.C436Y | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.094); catalogued as COSV53668769, COSV99648734; called by muse, mutect2, varscan2
- HMCN1 | c.1451T>G p.L484* | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | catalogued as COSV54924141; called by muse, mutect2
- IL17RD | c.2180G>A p.R727H | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs146776354; called by muse, mutect2, varscan2
- IRF2 | c.409A>T p.K137* | Nonsense Mutation (SNP) | VAF 60/85 reads (71%) | catalogued as COSV66929384, COSV66930079; called by muse, mutect2, varscan2
- KMT2D | c.3772C>T p.R1258W | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1202299145, COSV56468863; called by muse, mutect2, varscan2
- MED14 | c.4360C>A p.P1454T | Missense Mutation (SNP) | VAF 125/384 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.107); catalogued as COSV59948027; called by muse, mutect2, varscan2
- NRXN1 | c.45C>A p.C15* | Nonsense Mutation (SNP) | VAF 9/16 reads (56%) | catalogued as COSV68031122, COSV68031300; called by muse, mutect2, varscan2
- OR51S1 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs1025636880, COSV59059404; called by muse, mutect2, varscan2
- OR9G1 | c.490T>A p.S164T | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV56452916; called by muse, mutect2
- STAB1 | c.4439G>A p.R1480Q | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs144391932, COSV58736336; called by muse, mutect2, varscan2
- ZFC3H1 | c.3001G>T p.V1001L | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV66434719; called by muse, mutect2, varscan2
- PPP1R3F | c.1110_1111insTGATAGCCCCCACC p.P371* | Nonsense Mutation (INS) | VAF 20/104 reads (19%) | called by mutect2, varscan2
- ENTPD1 | c.1503G>A p.K501= | Silent (SNP) | VAF 67/168 reads (40%) | catalogued as rs750517800, COSV64603381; called by muse, mutect2, varscan2
- KIF20B | c.3444G>A p.A1148= (on ENST00000371728 / NM_001284259.2; = p.A1108= on NM_016195.4) | Silent (SNP) | VAF 35/92 reads (38%) | catalogued as rs764171222, COSV53312299; called by muse, mutect2, varscan2
- ONECUT2 | c.780C>T p.P260= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as COSV72203635; called by muse, mutect2, varscan2
- PCDH17 | c.3339G>A p.E1113= | Silent (SNP) | VAF 54/131 reads (41%) | catalogued as rs540534018, COSV64977013; called by muse, mutect2, varscan2
- SCRT2 | c.271C>T p.L91= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV55730255; called by muse, mutect2
- SNX14 | c.2577C>T p.N859= (on ENST00000314673 / NM_001350535.1; = p.N806= on NM_020468.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV59014650; called by muse, mutect2, varscan2
- SORL1 | c.4905A>G p.A1635= | Silent (SNP) | VAF 64/128 reads (50%) | catalogued as COSV52759111; called by muse, mutect2, varscan2
- AFDN | chr6:167826326 del CCAGCACCGCCCGTCTGGAA | 5'Flank (DEL) | VAF 10/30 reads (33%) | catalogued as rs750364387; called by mutect2, varscan2
